Somatic mutation profile of tumor specimen C3L-01039-03 (aliquot CPT0170340035) from CPTAC case C3L-01039, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 59.5 years (21,733 days).
Specimen C3L-01039-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f03f194-22b9-4d7a-8fce-c27c0cf50297.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01039-31 (Blood Derived Normal), aliquot CPT0167240002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6e31905-94d1-4024-acb0-c34857501064

The open-access MAF lists 59 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Nonsense Mutation 5, Intron 4, 3'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 52/446 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 51/432 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs146698596; called by mutect2, varscan2
- ALOX15B | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV101205571, COSV66479839; called by muse, mutect2, varscan2
- ATAD1 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 32/233 reads (14%) | catalogued as rs771096246; called by muse, mutect2, varscan2
- ATP12A | c.1573G>C p.A525P | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs967156411; called by muse, mutect2, varscan2
- CDH12 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 34/494 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as rs1291430724, COSV66409369; called by muse, mutect2
- CDH7 | c.105G>T p.K35N | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.202); catalogued as COSV59892387; called by muse, mutect2, varscan2
- COL3A1 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 54/457 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.431); catalogued as rs762028131, COSV58584897; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756106307, COSV62016664, COSV62040144; called by muse, mutect2, varscan2
- CSMD1 | c.5281G>A p.G1761S (on ENST00000520002; = p.G1760S on NM_033225.6) | Missense Mutation (SNP) | VAF 63/426 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV104408937; called by muse, varscan2
- DEFB119 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 35/328 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.538); catalogued as rs759707397, COSV100190928; called by mutect2, varscan2
- DOP1A | c.5981G>A p.R1994Q | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs376694061; called by muse, mutect2, varscan2
- EFNB3 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.984); catalogued as rs375397163; called by muse, mutect2
- ETV6 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 33/237 reads (14%) | catalogued as COSV56766946; called by muse, mutect2, varscan2
- GNL3L | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.283); catalogued as rs778008701; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1316C>T p.T439M | Missense Mutation (SNP) | VAF 50/430 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs780514194; called by mutect2, varscan2
- GPR158 | c.3082C>T p.H1028Y | Missense Mutation (SNP) | VAF 45/500 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1389889915; called by muse, mutect2
- IPO7 | c.3017A>G p.H1006R | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.093); catalogued as rs1431641189; called by muse, mutect2
- KBTBD3 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs1232867103; called by muse, mutect2, varscan2
- MYLK | c.4439G>A p.R1480Q | Missense Mutation (SNP) | VAF 36/390 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs1397757032, COSV60609666; called by muse, mutect2
- NLRP2 | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 59/630 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs540940476; called by muse, mutect2
- NPDC1 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs1359187922; called by muse, mutect2
- RIMBP2 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.972); catalogued as rs141970284; called by muse, mutect2
- SLITRK1 | c.1954C>T p.R652* | Nonsense Mutation (SNP) | VAF 42/359 reads (12%) | catalogued as COSV100999876, COSV65674503; called by muse, mutect2, varscan2
- SLITRK2 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1556944777, COSV59422879; called by muse, mutect2, varscan2
- TGFBR2 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 70/464 reads (15%) | catalogued as CM076559, COSV55451791; called by muse, mutect2, varscan2
- THPO | c.1193G>A p.R398H (on ENST00000649095 / NM_001290003.1; = p.R258H on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs147206404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC1 | c.643A>G p.M215V | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- ETV6 | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRZB | c.71T>A p.L24Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.328); called by muse, mutect2
- MACC1 | c.1454T>G p.F485C | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MEX3B | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDH18 | c.3085G>T p.V1029L | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- PLEKHN1 | c.1915A>T p.T639S (on ENST00000379409; = p.T587S on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/249 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- RECQL | c.1072A>T p.R358* | Nonsense Mutation (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- SLC7A4 | c.187G>C p.A63P | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPRY3 | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCF20 | c.479T>C p.F160S | Missense Mutation (SNP) | VAF 46/545 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- BACH2 | c.1779C>T p.S593= | Silent (SNP) | VAF 100/646 reads (15%) | catalogued as rs373751160; called by muse, mutect2, varscan2
- CBLB | c.1398C>T p.N466= | Silent (SNP) | VAF 74/729 reads (10%) | catalogued as rs56009631; called by muse, mutect2, varscan2
- DCDC1 | c.2412T>C p.H804= | Silent (SNP) | VAF 27/183 reads (15%) | catalogued as rs1401534192; called by muse, mutect2, varscan2
- DUXB | c.513C>T p.D171= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as rs774629326, COSV67756689; called by muse, mutect2
- EPPK1 | c.6336G>A p.V2112= | Silent (SNP) | VAF 22/250 reads (9%) | catalogued as COSV73261802; called by muse, mutect2
- FREM3 | c.4878C>T p.D1626= | Silent (SNP) | VAF 47/410 reads (11%) | catalogued as rs997227800; called by muse, mutect2, varscan2
- NACA | c.342C>T p.S114= | Silent (SNP) | VAF 33/159 reads (21%) | called by muse, mutect2, varscan2
- OR4C12 | c.705C>G p.L235= | Silent (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.381C>T p.N127= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as rs770162660, COSV53918941; called by muse, mutect2, varscan2
- SMIM17 | c.291C>G p.V97= | Silent (SNP) | VAF 26/261 reads (10%) | called by muse, mutect2
- THAP9 | c.1041A>G p.G347= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as rs1205769319; called by muse, mutect2, varscan2
- TSHZ3 | c.720C>T p.R240= | Silent (SNP) | VAF 11/150 reads (7%) | catalogued as rs760381593; called by muse, mutect2
- UGT2B17 | c.1015A>C p.R339= | Silent (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2, varscan2
- CSF2RA | c.*277C>T | 3'UTR (SNP) | VAF 5/39 reads (13%) | catalogued as rs774079021; called by muse, mutect2, varscan2
- F11R | c.*10G>A | 3'UTR (SNP) | VAF 21/322 reads (7%) | called by muse, mutect2
- GASK1B | c.910+42T>C | Intron (SNP) | VAF 37/365 reads (10%) | called by muse, mutect2
- KCNK16 | c.803-57C>A | Intron (SNP) | VAF 44/399 reads (11%) | called by muse, mutect2, varscan2
- SIGIRR | c.1069+107T>G | Intron (SNP) | VAF 25/276 reads (9%) | called by muse, mutect2
- THAP7 | chr22:21002647 T>C | 5'Flank (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- ZMIZ1 | c.957+479G>T | Intron (SNP) | VAF 24/263 reads (9%) | called by muse, mutect2
